Somatic mutation profile of tumor specimen C3N-02242-04 (aliquot CPT0215400009) from CPTAC case C3N-02242, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 47.7 years (17,416 days).
Specimen C3N-02242-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e66b777-37c8-480d-bcdd-b99c89a8a3b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02242-71 (Blood Derived Normal), aliquot CPT0215490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/953c5cd7-2ad7-4fbf-9a54-4c3ad1388f43

The open-access MAF lists 62 somatic variants for this specimen: 40 protein-altering or splice-affecting, 16 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 16, Intron 3, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1, RNA 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 14/229 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67980725; called by muse, mutect2
- AKAP3 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1345037350, COSV57420026; called by muse, mutect2
- ARHGAP25 | c.837del p.I280Sfs*10 (on ENST00000409202 / NM_001007231.3; = p.I272Sfs*10 on NM_014882.3) | Frame Shift Del (DEL) | VAF 27/280 reads (10%) | catalogued as COSV54909188; called by mutect2, pindel, varscan2
- ATRNL1 | c.3754T>C p.W1252R | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1259705266; called by muse, mutect2, varscan2
- CHMP4B | c.533A>C p.K178T | Missense Mutation (SNP) | VAF 23/370 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs768683361; called by muse, mutect2
- CPA4 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 32/527 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs3735053, COSV55982848; called by muse, mutect2
- CPNE7 | c.390G>T p.M130I | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs771806328; called by muse, mutect2, varscan2
- FGFR2 | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 52/352 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1311258996, COSV100336630, COSV60659184; called by muse, mutect2, varscan2
- MC3R | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 60/468 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1286756644, COSV54762849; called by muse, mutect2, varscan2
- NT5DC1 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs763157437, COSV60311181; called by muse, mutect2
- TAS2R13 | c.306C>G p.I102M | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); catalogued as COSV66831809; called by muse, mutect2
- TGM5 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 41/575 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as rs766923465; called by muse, mutect2
- TMEM198 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1199903648, COSV99705138; called by muse, mutect2
- TP53 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV52661518, COSV52689110; called by muse, mutect2
- UBE4B | c.1273G>C p.D425H (on ENST00000343090 / NM_001105562.3; = p.D296H on NM_006048.5) | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV99036787; called by muse, mutect2
- ZFYVE28 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1419088323, COSV52110916; called by muse, mutect2
- ZNF697 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1446943112; called by muse, mutect2
- ARHGAP36 | c.222A>T p.R74S | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2
- BCOR | c.4036C>G p.L1346V (on ENST00000378444 / NM_001123385.2; = p.L1312V on NM_017745.6) | Missense Mutation (SNP) | VAF 33/455 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.178); called by muse, mutect2
- BORCS8 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2
- CELF5 | c.180C>G p.D60E | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.224); called by muse, mutect2
- CXCL2 | c.246G>C p.Q82H | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2
- DOCK10 | c.1178G>A p.R393K | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- DPYD | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2
- GOLGA4 | c.4300C>T p.Q1434* | Nonsense Mutation (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- GTF2A1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- IRS4 | c.3077C>A p.T1026K | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2
- LARGE2 | c.964C>G p.H322D | Missense Mutation (SNP) | VAF 29/410 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2
- LOXHD1 | c.4729T>C p.F1577L | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.031); called by muse, mutect2
- MYH13 | c.4450G>C p.E1484Q | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- PCNT | c.6361G>A p.D2121N | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.092); called by muse, mutect2
- PGM1 | c.1467C>T p.G489= | Splice Region (SNP) | VAF 33/487 reads (7%) | called by muse, mutect2
- PLEKHH3 | c.1244C>G p.A415G | Missense Mutation (SNP) | VAF 31/431 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2
- RABGEF1 | c.1224A>T p.E408D (on ENST00000439720 / NM_001287061.2; = p.E395D on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/390 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- RPN2 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- SNRPD1 | c.299G>T p.R100I | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.944); called by muse, mutect2
- SPRED2 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 25/331 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- TENM4 | c.5942C>T p.P1981L | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- TMCC1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 21/338 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.412); called by muse, mutect2
- UMODL1 | c.1372C>T p.L458F | Missense Mutation (SNP) | VAF 25/419 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); called by muse, mutect2
- BARD1 | c.999T>A p.S333= | Silent (SNP) | VAF 24/156 reads (15%) | called by muse, varscan2
- BTK | c.111C>G p.L37= | Silent (SNP) | VAF 17/264 reads (6%) | called by muse, mutect2
- CAMK2A | c.1392C>T p.I464= (on ENST00000348628 / NM_171825.2; = p.I475= on NM_015981.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/472 reads (7%) | catalogued as rs912865720, COSV62245003; called by muse, mutect2
- FAT2 | c.1746G>A p.S582= | Silent (SNP) | VAF 24/199 reads (12%) | catalogued as rs765690558, COSV55813008; called by muse, mutect2, varscan2
- GLT6D1 | c.141G>A p.T47= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as rs367832463, COSV65628435; called by muse, mutect2, varscan2
- GUF1 | c.1953C>T p.N651= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as rs183888731; called by muse, mutect2
- HIF1AN | c.222G>C p.L74= | Silent (SNP) | VAF 31/201 reads (15%) | called by muse, mutect2
- LAD1 | c.1098C>A p.L366= | Silent (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- NCAPG | c.903C>G p.L301= | Silent (SNP) | VAF 10/232 reads (4%) | catalogued as COSV52270778; called by muse, mutect2
- OAF | c.60C>G p.L20= | Silent (SNP) | VAF 42/411 reads (10%) | catalogued as rs1226408439; called by muse, mutect2, varscan2
- PFKFB3 | c.768G>A p.E256= | Silent (SNP) | VAF 44/589 reads (7%) | called by muse, mutect2
- RNF19B | c.43C>T p.L15= | Silent (SNP) | VAF 24/449 reads (5%) | called by muse, mutect2
- SYMPK | c.2418C>T p.H806= | Silent (SNP) | VAF 31/430 reads (7%) | catalogued as rs1210436548; called by muse, mutect2
- TEF | c.861C>G p.G287= | Silent (SNP) | VAF 16/308 reads (5%) | called by muse, mutect2
- USP9X | c.558C>T p.I186= | Silent (SNP) | VAF 14/284 reads (5%) | catalogued as rs1188501864; called by muse, mutect2
- ZZEF1 | c.3231G>A p.R1077= | Silent (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- DTX2 | c.1151-67C>T | Intron (SNP) | VAF 133/569 reads (23%) | called by muse, mutect2, varscan2
- GLB1L2 | c.-50G>A | 5'UTR (SNP) | VAF 34/317 reads (11%) | called by muse, mutect2, varscan2
- IL20RB | c.89-79C>T | Intron (SNP) | VAF 12/100 reads (12%) | catalogued as COSV100291188; called by muse, mutect2, varscan2
- SMPX | c.*275G>C | 3'UTR (SNP) | VAF 13/306 reads (4%) | called by muse, mutect2
- SPINDOC | c.935-3798T>G | Intron (SNP) | VAF 20/296 reads (7%) | called by muse, mutect2
- Vault | n.16C>G | RNA (SNP) | VAF 11/176 reads (6%) | called by muse, mutect2
